Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CQ-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender: F
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Parathyroid: Left Biopsy, Lower
2. right lower parathyroid -QS
3. Thyroid total stitch upper right pole

Reviewed by (signature)	[Signature]	

Diagnosis

1. No pathological diagnosis: Parathyroid (left lower) biopsy.
2. No pathological diagnosis: Parathyroid (right lower) biopsy.
3. Multifocal papillary carcinoma, dominant 1.8 cm, follicular variant, left: Thyroid
Metastatic papillary thyroid carcinoma: Lymph node, 1 of 3
-Total thyroidectomy specimen.

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 5.7 cm 2.4 cm 1.5 cm Left lobe: 5.2 cm 3.1 cm 1.7 cm Isthmus +/- pyramidal lobe: 4.2 cm 1.4 cm 0.8 cm
Specimen Weight:	35 g

ICD-0-3

carcinoma, papillary,
Follicular variant 8340/3
Site: thyroid C73.9 [Signature]

[page 2 of 3]
Tumor Focality: Multifocal, bilateral
Multifocal, midline (isthmus)

----- DOMINANT TUMOR -----

Tumor Laterality: ~~Left lobe~~

Tumor Size: Greatest dimension: 1.8cm
Additional dimension: 1.5 cm
Additional dimension: 1.5 cm

Histologic Type: ~~Papillary carcinoma, follicular variant~~ *per TSS, follicular variant = 100%*
Follicular architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: Totally encapsulated

Tumor Capsular Invasion: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Left lobe
Isthmus

Tumor Size: Greatest dimension: 1.5cm

Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: Partially encapsulated

Tumor Capsular Invasion: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

TNM Descriptors: m (multiple primary tumors)

Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid

Regional Lymph Nodes (pN): pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes
Number of regional lymph nodes examined: 3
Number of regional lymph nodes involved: 1
Lymph Node, Extranodal Extension Not identified

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Other: Multiple additional papillary microcarcinomas identified in right lobe (one measuring 0.1cm) and in left lobe (at least 3 foci).

Ancillary Studies: Type: IHC
Results: Two microscopic deposits of tumor which stain positive for TTF1 and CK are identified in one perithyroidal lymph node (left).

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

[page 3 of 3]
verified by:

Gross Description

1. The specimen labelled with the patient's name and as "left biopsy lower" consists of a piece of parathyroid tissue that weighs 0.001 g and measures 0.2 x 0.1 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen tissue resubmitted

2. The specimen labelled with the patient's name and as "right lower parathyroid" consists of a piece of parathyroid tissue that weighs 0.001 g and measures 0.2 x 0.1 x 0.1 cm. It is frozen for intraoperative consultation.

2A frozen tissue resubmitted

3. The specimen labeled with the patient's name and as "total thyroid stitch upper right pole" consists of a thyroid gland that is oriented with suture at right upper pole and weighs 35 g. The right lobe measures 5.7 cm SI x 2.4 cm ML x 1.5 cm AP, the left lobe measures 5.2 cm SI x 3.1 cm ML x 1.7 cm AP and the isthmus measures 4.2 cm SI x 1.4 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with blue dye. The lower left lobe contains a well delineated nodule that measures 1.8 cm SI x 1.5 cm ML x 1.5 cm AP. The isthmus also contains a well delineated nodule that measures 1.5 cm SI x 1.1 cm ML x 0.8 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-K right lobe, superior to inferior

3L-N isthmus

3O-X left lobe, superior to inferior

Quick Section Diagnosis

QS1A: Parathyroid tissue
(Reported)

QS2A: Parathyroid tissue
(Reported)

Source: NCI Genomic Data Commons file ad7ecf3c-175d-40a3-95ab-68448a5713bd (TCGA-EM-A2CQ.54D48CFB-957A-4233-8DE7-8B867862D894.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).